Somatic mutation profile of tumor specimen TCGA-AZ-4308-01A (aliquot TCGA-AZ-4308-01A-01D-1408-10) from TCGA case TCGA-AZ-4308, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 47.4 years (17,321 days).
Specimen TCGA-AZ-4308-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ecf09fd7-8154-48b7-a98a-f041d8a0b9e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AZ-4308-10A (Blood Derived Normal), aliquot TCGA-AZ-4308-10A-01D-2188-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f476402-e3f8-44c9-bafd-971288617f42

The open-access MAF lists 68 somatic variants for this specimen: 54 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 11, Nonsense Mutation 6, Splice Site 2, Intron 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COQ8A | c.1532C>T p.T511M | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs578189699, COSV62016205; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.8086C>T p.R2696* | Nonsense Mutation (SNP) | VAF 30/78 reads (38%) | catalogued as rs587783680, COSV63284064; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 26/36 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AASDHPPT | c.86G>A p.S29N | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV53789808; called by muse, mutect2, varscan2
- ABCC11 | c.497A>G p.D166G | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100750588; called by muse, mutect2, varscan2
- APC | c.3441C>G p.Y1147* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as CD972000, CM058099, CM106367, COSV57384006, COSV99965890; called by muse, mutect2, varscan2
- BCL9 | c.1075C>T p.R359W | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781842513, COSV99324615; called by muse, mutect2, varscan2
- C1RL | c.858C>A p.Y286* | Nonsense Mutation (SNP) | VAF 26/59 reads (44%) | catalogued as COSV99864485; called by muse, mutect2, varscan2
- CEP85L | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.185); catalogued as COSV100682510; called by muse, varscan2
- CLDN17 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as rs182327550, COSV99729038; called by muse, mutect2, varscan2
- COL1A2 | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99798817; called by muse, mutect2, varscan2
- COL5A2 | c.3880C>T p.R1294C | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758136981, COSV66409238, COSV66412921; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH2 | c.7949+2T>C p.X2650_splice | Splice Site (SNP) | VAF 11/32 reads (34%) | catalogued as COSV101209066; called by muse, mutect2, varscan2
- DROSHA | c.1897G>T p.E633* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as COSV100757509; called by muse, mutect2, varscan2
- ENOX1 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs779420488, COSV54909185; called by muse, mutect2
- FGD5 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs568677261, COSV53241485; called by muse, mutect2
- GFPT1 | c.1054G>A p.E352K (on ENST00000357308 / NM_001244710.2; = p.E334K on NM_002056.4) | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100622694; called by muse, mutect2, varscan2
- GRIA4 | c.1433A>G p.D478G | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as COSV99229488; called by muse, mutect2, varscan2
- HSPG2 | c.2480A>T p.D827V | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs752992263, COSV101020461; called by muse, mutect2, varscan2
- ITGB3 | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as rs75427428, CM984088, COSV101457551; called by muse, mutect2, varscan2
- KCNH5 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT tolerated (0.06); PolyPhen benign (0.327); catalogued as rs371757416; called by muse, mutect2, varscan2
- KDM2B | c.1399C>T p.R467* | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | catalogued as COSV100997253; called by muse, mutect2
- LIMD1 | c.845A>G p.N282S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as COSV99836810; called by muse, mutect2, varscan2
- LRG1 | c.740A>G p.K247R | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV100014679; called by muse, mutect2, varscan2
- MYH9 | c.1153T>G p.F385V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as COSV99338036; called by muse, varscan2
- NFE2 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV100380687; called by muse, mutect2, varscan2
- NLRC5 | c.3113+1G>A p.X1038_splice | Splice Site (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99346645; called by muse, mutect2, varscan2
- NRAP | c.2642T>C p.V881A (on ENST00000359988 / NM_001322945.2; = p.V846A on NM_006175.4) | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1230591704, COSV100748314; called by muse, mutect2, varscan2
- NUTM2F | c.1452G>T p.E484D | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV99479933; called by muse, mutect2, varscan2
- OR4A5 | c.71C>A p.A24E | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.365); catalogued as COSV60523557; called by muse, mutect2, varscan2
- OR5B21 | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.608); catalogued as COSV64482103, COSV64482343; called by muse, mutect2, varscan2
- PCDH15 | c.215C>T p.T72I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1189952332, COSV100216734; called by muse, mutect2, varscan2
- PCDH9 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.799); catalogued as COSV100118892, COSV60534355; called by muse, mutect2, varscan2
- PCDHB12 | c.2156C>A p.A719E | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.852); catalogued as COSV53398785, COSV53399160; called by muse, mutect2
- PCDHGB3 | c.1262C>T p.T421M | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs772257649, COSV53899106; called by muse, mutect2, varscan2
- PHF13 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.734); catalogued as rs141668960; called by muse, mutect2, varscan2
- PSMD5 | c.1490C>T p.T497M | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as rs752722111, COSV99270670; called by muse, mutect2, varscan2
- PTEN | c.499A>G p.T167A | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as rs1210737543, CD075529, COSV64288434, COSV64311397; called by muse, mutect2, varscan2
- REXO1 | c.2933C>A p.T978N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV99402080; called by muse, mutect2, varscan2
- RPS11 | c.107A>G p.Y36C | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV54526926; called by muse, mutect2, varscan2
- RRP7A | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1312213244, COSV59900097; called by muse, mutect2, varscan2
- RSRC1 | c.101C>A p.T34K | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.342); catalogued as COSV99905552; called by muse, mutect2, varscan2
- SEPHS1 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs1298410502, COSV100525700; called by muse, mutect2
- SF3B2 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.968); catalogued as rs775280803, COSV100488294; called by muse, mutect2, varscan2
- SLC25A18 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100541102; called by muse, mutect2, varscan2
- TFB1M | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100905150; called by muse, mutect2, varscan2
- TMBIM4 | c.226T>C p.F76L | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV53968057, COSV99660216; called by muse, mutect2, varscan2
- TMCO4 | c.1630C>T p.R544C | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs758312088, COSV53872684; called by muse, mutect2, varscan2
- TRIM49 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.208); catalogued as COSV61671423, COSV61671907; called by muse, mutect2, varscan2
- TRPM6 | c.5356G>A p.V1786I | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs142946646, COSV62520097, COSV62521179; called by muse, mutect2, varscan2
- VCAN | c.3626C>T p.T1209I | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.23); catalogued as COSV99424939; called by muse, mutect2, varscan2
- WBP4 | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65274363; called by muse, mutect2, varscan2
- ZNF607 | c.1330A>G p.T444A | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs1291067426, COSV100777831; called by muse, mutect2, varscan2
- ZNF804A | c.2441G>A p.R814Q | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs765819874, COSV56437566; called by muse, mutect2, varscan2
- AFAP1L2 | c.525C>T p.D175= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs373379522; called by muse, mutect2, varscan2
- AMDHD2 | c.279C>T p.L93= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as rs150383216, COSV53551648; called by muse, mutect2, varscan2
- COPS7A | c.621G>A p.Q207= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV99976404; called by muse, mutect2, varscan2
- LRRK2 | c.7005C>A p.L2335= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV100109441, COSV54146278; called by muse, mutect2, varscan2
- MOV10L1 | c.1254C>T p.D418= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs144338444; called by muse, mutect2
- NCAM2 | c.2487A>G p.Q829= | Silent (SNP) | VAF 60/192 reads (31%) | catalogued as rs1569147043, COSV99521696; called by muse, mutect2, varscan2
- SIX6 | c.561A>T p.A187= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV59802957; called by muse, mutect2, varscan2
- STAB1 | c.2421C>T p.A807= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100401330; called by muse, mutect2, varscan2
- TMEM125 | c.357C>T p.L119= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as rs140782393; called by muse, mutect2, varscan2
- XKR9 | c.480G>A p.A160= | Silent (SNP) | VAF 34/132 reads (26%) | catalogued as COSV68772840; called by muse, mutect2, varscan2
- ZNF423 | c.126C>T p.C42= (on ENST00000563137 / NM_001379286.1; = p.C34= on NM_015069.4) | Silent (SNP) | VAF 53/140 reads (38%) | catalogued as rs139517505; called by muse, mutect2, varscan2
- FGFR3 | c.*987A>T | 3'UTR (SNP) | VAF 24/62 reads (39%) | catalogued as COSV99600781; called by muse, mutect2, varscan2
- LINC01587 | n.183C>A | RNA (SNP) | VAF 33/94 reads (35%) | called by muse, mutect2, varscan2
- LRRFIP1 | c.250-9055G>T | Intron (SNP) | VAF 20/40 reads (50%) | catalogued as COSV99790471; called by muse, mutect2, varscan2
